Somatic mutation profile of tumor specimen 0DU3KW from CCDI case PBCKIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,186 days).
Specimen 0DU3KW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8821ae3d-eef4-4443-b765-4eb41f2e0e10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ce28f08-31bc-4b8b-8743-edfe82dccf9f

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, 3'UTR 2, Missense Mutation 2, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZHX3 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 16/554 reads (3%) | catalogued as rs1320639895, COSV58383599; called by muse, mutect2
- BCOR | c.4087_4088del p.C1363Qfs*45 (on ENST00000378444 / NM_001123385.2; = p.C1329Qfs*45 on NM_017745.6) | Frame Shift Del (DEL) | VAF 190/720 reads (26%) | called by pindel, varscan2
- GPR137B | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 16/472 reads (3%) | called by muse, mutect2
- KDM6A | c.270del p.V91Wfs*9 | Frame Shift Del (DEL) | VAF 103/344 reads (30%) | called by mutect2, pindel, varscan2
- KRT37 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 352/890 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTM1 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 187/597 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.3291C>T p.S1097= | Silent (SNP) | VAF 40/342 reads (12%) | catalogued as rs746547019; called by muse, mutect2, varscan2
- IL31RA | c.*43A>C | 3'UTR (SNP) | VAF 94/291 reads (32%) | called by muse, mutect2, varscan2
- MYBBP1A | c.*500A>T | 3'UTR (SNP) | VAF 18/262 reads (7%) | catalogued as COSV54605199; called by muse, mutect2
